Somatic mutation profile of tumor specimen TCGA-43-2581-01A (aliquot TCGA-43-2581-01A-01W-0877-08) from TCGA case TCGA-43-2581, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.8 years (17,447 days).
Specimen TCGA-43-2581-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a535626-340a-49ec-8142-8c15a456c124.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-2581-11A (Solid Tissue Normal), aliquot TCGA-43-2581-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e461e815-be52-4d3c-9850-77530a7c42fa

The open-access MAF lists 750 somatic variants for this specimen: 591 protein-altering or splice-affecting, 139 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 511, Silent 139, Nonsense Mutation 44, Frame Shift Del 13, Splice Site 9, Intron 9, Splice Region 8, RNA 5, Frame Shift Ins 3, 5'UTR 3, Translation Start Site 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 36/131 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV99933534; called by muse, mutect2, varscan2
- ABCA4 | c.5172G>T p.W1724C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM161733, HM070135, COSV100933331; called by muse, mutect2
- ABCB10 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV100748099; called by muse, mutect2, varscan2
- ABCB5 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 131/722 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.615); catalogued as COSV99330081; called by muse, mutect2, varscan2
- ABCC8 | c.1402A>T p.I468F | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV100217841, COSV56852322; called by muse, mutect2
- AC100868.1 | c.1850C>A p.S617Y | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as COSV51841113, COSV99227187; called by muse, mutect2, varscan2
- ACER1 | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 164/798 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100034160; called by muse, mutect2, varscan2
- ACKR1 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100929700; called by muse, mutect2, varscan2
- ACSM2A | c.43G>C p.G15R | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV54584620, COSV99525817; called by muse, mutect2, varscan2
- ACSS3 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99699606; called by muse, mutect2, varscan2
- ACTBL2 | c.898T>G p.L300V | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as COSV101379437; called by muse, varscan2
- ACTL9 | c.544G>C p.V182L | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100185597, COSV61004846; called by muse, mutect2, varscan2
- ADAD1 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.437); catalogued as COSV99636426; called by muse, mutect2, varscan2
- ADAM15 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.762); catalogued as COSV99665451; called by muse, mutect2, varscan2
- ADAMTS1 | c.2274G>C p.Q758H | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV53169802, COSV99536615; called by muse, mutect2, varscan2
- ADAMTS5 | c.846G>T p.L282F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs762742485, COSV99538510; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2061G>T p.Q687H | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101002108; called by muse, mutect2, varscan2
- ADARB1 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100653560; called by muse, mutect2, varscan2
- ADGRB3 | c.1718G>C p.R573T | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101002058; called by muse, mutect2, varscan2
- ADGRF3 | c.2882C>G p.P961R (on ENST00000311519 / NM_001145168.1; = p.P762R on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100274968, COSV100275534; called by muse, mutect2, varscan2
- ADH1A | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99266024; called by muse, mutect2, varscan2
- ADH1B | c.920T>C p.M307T | Missense Mutation (SNP) | VAF 109/518 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100520896; called by muse, mutect2, varscan2
- AFG1L | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780217981, COSV100934043; called by muse, mutect2, varscan2
- AGMO | c.63C>A p.Y21* | Nonsense Mutation (SNP) | VAF 43/223 reads (19%) | catalogued as COSV100694903; called by muse, varscan2
- AIM2 | c.396+2T>C p.X132_splice | Splice Site (SNP) | VAF 43/250 reads (17%) | catalogued as COSV100931168; called by muse, mutect2, varscan2
- AMER1 | c.2796C>G p.D932E | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100367174; called by muse, mutect2, varscan2
- ANKEF1 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV101001089; called by muse, mutect2, varscan2
- ANKRD13C | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV99257904; called by muse, mutect2, varscan2
- ANKRD24 | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV99518285; called by muse, mutect2, varscan2
- ANKRD30A | c.3505A>T p.K1169* (on ENST00000611781; = p.K1113* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 74/370 reads (20%) | catalogued as COSV100654599; called by muse, mutect2
- ANKRD30A | c.3507A>T p.K1169N (on ENST00000611781; = p.K1113N on NM_052997.2) | Missense Mutation (SNP) | VAF 75/363 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1209644461, COSV100654558; called by muse, mutect2
- ANKRD45 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV100322732; called by muse, mutect2, varscan2
- ANKRD7 | c.421G>T p.V141F | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99501428; called by muse, mutect2, varscan2
- ANKS4B | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100290000; called by muse, mutect2, varscan2
- ANO5 | c.1373G>A p.W458* | Nonsense Mutation (SNP) | VAF 15/131 reads (11%) | catalogued as COSV100202345; called by muse, mutect2, varscan2
- ANXA4 | c.563G>T p.W188L | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.558); catalogued as COSV101268850; called by muse, mutect2, varscan2
- AP2B1 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99251825; called by muse, mutect2, varscan2
- APC | c.8381G>C p.S2794T | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV57389610, COSV99970895; called by muse, mutect2, varscan2
- APOB | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV99268636; called by muse, mutect2, varscan2
- ARHGAP30 | c.3221A>T p.Q1074L (on ENST00000368013 / NM_001025598.2; = p.Q863L on NM_181720.3) | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.306); catalogued as COSV100920123, COSV100920560; called by muse, mutect2, varscan2
- ARHGEF18 | c.1238G>T p.R413M (on ENST00000359920 / NM_001130955.2; = p.R309M on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV100150131; called by muse, mutect2, varscan2
- ARID1B | c.3583G>T p.G1195C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99273097; called by mutect2, varscan2
- ASAP2 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as COSV99857023; called by muse, mutect2, varscan2
- ASPRV1 | c.385T>A p.W129R | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100208671; called by muse, mutect2, varscan2
- ASS1 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100752869; called by muse, mutect2, varscan2
- ASTN1 | c.1968C>A p.F656L | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV99923454; called by muse, mutect2, varscan2
- ASXL3 | c.5737G>C p.V1913L | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV99327030; called by muse, mutect2, varscan2
- ATAD2 | c.482G>T p.R161I | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99785493; called by muse, mutect2
- ATP10B | c.2100G>T p.E700D | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV100515944; called by muse, mutect2, varscan2
- ATP10D | c.2063G>T p.S688I | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV99906294; called by muse, mutect2, varscan2
- ATP2B1 | c.2620G>T p.A874S | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs570457928, COSV53803084, COSV99666296; called by muse, mutect2, varscan2
- AVPR1A | c.1076G>T p.C359F | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100146930; called by muse, mutect2, varscan2
- AWAT2 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as rs780915226, COSV52144878; called by muse, mutect2
- BANK1 | c.1602G>A p.M534I | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100537009, COSV100537050; called by muse, mutect2
- BOLL | c.600+2T>A p.X200_splice | Splice Site (SNP) | VAF 23/103 reads (22%) | catalogued as COSV99987507; called by muse, mutect2, varscan2
- BRD8 | c.2835C>A p.N945K | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV99137858; called by muse, mutect2
- BRWD1 | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100314335; called by muse, mutect2, varscan2
- BTK | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.991); catalogued as CM952088, COSV58118475; called by muse, mutect2, varscan2
- C10orf90 | c.23G>C p.G8A | Missense Mutation (SNP) | VAF 68/333 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52949332, COSV99505386; called by muse, mutect2, varscan2
- C9orf24 | c.245A>T p.Y82F | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99898169; called by muse, mutect2, varscan2
- CACNA1A | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 90/574 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100803426; called by muse, mutect2, varscan2
- CACNA1E | c.6676C>A p.R2226S (on ENST00000367573 / NM_001205293.3; = p.R2183S on NM_000721.4) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV100705332, COSV100705796; called by muse, mutect2, varscan2
- CADM3 | c.843G>T p.E281D (on ENST00000368125 / NM_001127173.3; = p.E315D on NM_021189.5) | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.101); catalogued as COSV100930441; called by muse, mutect2, varscan2
- CALCR | c.1211C>A p.A404E (on ENST00000649521 / NM_001164737.2; = p.A388E on NM_001742.4) | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749628730, COSV100810913, COSV64009509; called by muse, mutect2, varscan2
- CALU | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99975973; called by muse, mutect2, varscan2
- CASD1 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as rs780009738, COSV99803191; called by muse, mutect2, varscan2
- CCDC63 | c.1393C>A p.R465S | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs762320804, COSV57528395, COSV57531719; called by muse, mutect2, varscan2
- CCDC88C | c.3358G>T p.V1120L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101106359; called by muse, varscan2
- CCL24 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs989134700, COSV99768899; called by muse, mutect2, varscan2
- CD180 | c.858C>A p.F286L | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as rs746380841, COSV99842454; called by muse, mutect2, varscan2
- CD6 | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100533329; called by muse, mutect2, varscan2
- CDADC1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV99212622; called by muse, mutect2, varscan2
- CDH10 | c.662C>G p.A221G | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100053468, COSV52593832, COSV52594063; called by muse, mutect2, varscan2
- CDH12 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | catalogued as COSV101203443, COSV101203477; called by muse, mutect2, varscan2
- CDK14 | c.635A>T p.Y212F (on ENST00000380050 / NM_001287135.2; = p.Y194F on NM_012395.3) | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99727414; called by muse, mutect2, varscan2
- CDK5R2 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.069); catalogued as rs1233130991, COSV100226007; called by muse, mutect2, varscan2
- CDKL2 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277241; called by muse, mutect2, varscan2
- CELSR2 | c.826A>G p.T276A | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.872); catalogued as COSV99604964; called by muse, mutect2, varscan2
- CEP135 | c.1111-1G>A p.X371_splice | Splice Site (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99954969; called by muse, mutect2
- CEP170 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100318060; called by muse, mutect2, varscan2
- CES5A | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51866011, COSV99308157; called by mutect2, varscan2
- CFAP36 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs372141624; called by muse, mutect2, varscan2
- CGN | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99642976; called by muse, mutect2, varscan2
- CGNL1 | c.853G>C p.G285R | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99849346; called by muse, mutect2
- CHAMP1 | c.2144G>A p.C715Y | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100778893; called by muse, mutect2, varscan2
- CHD9 | c.6782A>T p.D2261V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99529890; called by muse, mutect2, varscan2
- CHI3L2 | c.319G>C p.G107R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100869338; called by muse, mutect2, varscan2
- CLCN1 | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100578663; called by muse, mutect2, varscan2
- CMYA5 | c.8578G>T p.D2860Y | Missense Mutation (SNP) | VAF 116/670 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV101484451, COSV71409422; called by muse, mutect2, varscan2
- CNBD1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV101575307; called by muse, mutect2
- CNKSR2 | c.1933A>G p.K645E | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99670177; called by muse, mutect2, varscan2
- CNOT8 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99597299; called by muse, mutect2, varscan2
- CNTNAP2 | c.2795G>T p.G932V | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228596882, COSV100673819; called by muse, varscan2
- CNTNAP3 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.934); catalogued as COSV99905822; called by muse, mutect2, varscan2
- COBL | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.666); catalogued as COSV99474539; called by muse, varscan2
- COL22A1 | c.2858A>T p.E953V | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100280869, COSV100281249; called by muse, mutect2, varscan2
- COL24A1 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 13/134 reads (10%) | catalogued as COSV100994178; called by muse, mutect2
- COL25A1 | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1330565456, COSV101211719; called by muse, mutect2, varscan2
- COL27A1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1266183112, COSV100621398; called by muse, mutect2, varscan2
- COL4A1 | c.3589G>C p.A1197P | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV101011639; called by muse, mutect2, varscan2
- COL9A1 | c.2152G>T p.G718* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV100295860, COSV57892938; called by muse, mutect2, varscan2
- COPG1 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV100136032; called by muse, mutect2, varscan2
- CORIN | c.1766C>A p.S589* | Nonsense Mutation (SNP) | VAF 50/239 reads (21%) | catalogued as rs1176505390, COSV99904640; called by muse, mutect2, varscan2
- CPB1 | c.1250A>T p.Y417F | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV99294598; called by muse, mutect2
- CPEB1 | c.1763G>T p.R588L (on ENST00000617958; = p.R523L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99918075; called by muse, mutect2, varscan2
- CPQ | c.540C>G p.Y180* | Nonsense Mutation (SNP) | VAF 40/313 reads (13%) | catalogued as COSV99615497; called by muse, mutect2, varscan2
- CRELD2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs370691392; called by muse, mutect2, varscan2
- CRHBP | c.437G>C p.S146T | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99169548; called by muse, mutect2, varscan2
- CSF1R | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 34/163 reads (21%) | catalogued as COSV99643404; called by muse, mutect2, varscan2
- CSMD1 | c.3607G>T p.D1203Y (on ENST00000520002; = p.D1202Y on NM_033225.6) | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs749555971, COSV100154840, COSV59297299; called by muse, mutect2, varscan2
- CTAGE1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 96/606 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV101194725; called by muse, mutect2, varscan2
- CTCFL | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99713491; called by muse, mutect2, varscan2
- CTNNA3 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146777494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUBN | c.6179G>T p.G2060V | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100913721; called by muse, mutect2, varscan2
- CXCL2 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs775781780, COSV99933233; called by mutect2, varscan2
- CXCL5 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs767718489, COSV99932964; called by muse, mutect2, varscan2
- CYP11A1 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762145358, COSV99166293; called by muse, mutect2, varscan2
- CYYR1 | c.453C>G p.N151K | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.394); catalogued as rs781224725, COSV100177711, COSV54832337; called by muse, mutect2, varscan2
- DAB2 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100298456; called by muse, mutect2, varscan2
- DCAF12L1 | c.1289C>A p.A430E | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64421692, COSV64422635; called by muse, mutect2, varscan2
- DCAF12L1 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100948482; called by muse, varscan2
- DCSTAMP | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 60/238 reads (25%) | catalogued as COSV99887091; called by muse, mutect2, varscan2
- DDX10 | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490062; called by muse, mutect2, varscan2
- DENND3 | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV99371886; called by muse, mutect2, varscan2
- DENND4B | c.318G>T p.G106= | Splice Region (SNP) | VAF 47/123 reads (38%) | catalogued as COSV100339406; called by muse, mutect2, varscan2
- DGKI | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV99937829; called by muse, mutect2, varscan2
- DHRS3 | c.596T>C p.M199T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV100879714; called by muse, mutect2, varscan2
- DMGDH | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV99669628; called by muse, mutect2
- DNAAF2 | c.500C>A p.T167K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100024270; called by mutect2, varscan2
- DNAH17 | c.12907C>G p.R4303G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99428580; called by muse, mutect2, varscan2
- DPCD | c.203T>A p.V68E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100924367; called by muse, mutect2, varscan2
- DRD2 | c.960C>A p.D320E | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100670261; called by muse, mutect2, varscan2
- DSG4 | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV100356526; called by muse, mutect2, varscan2
- DTNA | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 65/346 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV52011516; called by muse, mutect2, varscan2
- DUSP26 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.06); catalogued as COSV99823608; called by muse, mutect2, varscan2
- EDC4 | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV100739359, COSV62765887; called by muse, mutect2, varscan2
- EFL1 | c.1402G>T p.G468W | Missense Mutation (SNP) | VAF 72/730 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV99189160; called by muse, mutect2, varscan2
- ELP1 | c.2942G>T p.S981I | Missense Mutation (SNP) | VAF 65/430 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV101010544; called by muse, mutect2, varscan2
- EPG5 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.04); catalogued as COSV99958311; called by muse, mutect2, varscan2
- EPHA10 | c.459C>A p.D153E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100140208; called by muse, varscan2
- EPHA3 | c.1781G>A p.R594K | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs758942025, COSV100349587; called by muse, varscan2
- EPHB2 | c.2612C>T p.P871L (on ENST00000400191 / NM_001309193.2; = p.P872L on NM_004442.7) | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763557854, COSV101007479; called by muse, mutect2
- ERBB4 | c.630G>T p.R210S | Missense Mutation (SNP) | VAF 104/342 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV53550433; called by muse, varscan2
- ERICH3 | c.4381A>T p.S1461C | Missense Mutation (SNP) | VAF 91/424 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.85); catalogued as COSV100446073; called by muse, mutect2, varscan2
- ERICH3 | c.2815G>C p.V939L | Missense Mutation (SNP) | VAF 91/412 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV100446074; called by muse, mutect2, varscan2
- ESRRB | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV99835908; called by muse, mutect2, varscan2
- FAM135B | c.3291G>T p.Q1097H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV99428522; called by muse, mutect2
- FANCB | c.2173A>T p.T725S | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as COSV100146719; called by muse, mutect2, varscan2
- FAT3 | c.10217G>T p.R3406L | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53103909; called by muse, mutect2, varscan2
- FAT3 | c.13501A>T p.S4501C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV99972239; called by mutect2, varscan2
- FAT4 | c.5920G>C p.G1974R | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100627684, COSV100630539; called by muse, mutect2
- FAT4 | c.11449G>C p.G3817R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627355, COSV100630540; called by muse, mutect2, varscan2
- FBN2 | c.3230G>T p.C1077F | Missense Mutation (SNP) | VAF 68/313 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99331359; called by muse, mutect2, varscan2
- FBN2 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99331360; called by muse, mutect2, varscan2
- FBXL14 | c.412A>T p.I138L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.785); catalogued as COSV100201670; called by muse, mutect2, varscan2
- FEZF1 | c.150C>A p.H50Q | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV100484576; called by muse, mutect2, varscan2
- FGF8 | c.282G>T p.M94I (on ENST00000344255 / NM_033164.4; = p.M76I on NM_006119.6) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV100199480; called by muse, mutect2
- FGFR1 | c.2366C>G p.S789C (on ENST00000447712 / NM_023110.3; = p.S787C on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100249539; called by muse, mutect2, varscan2
- FLG2 | c.1391T>C p.L464S | Missense Mutation (SNP) | VAF 210/634 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101166300; called by muse, mutect2, varscan2
- FMO1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773457494, COSV100707996; called by muse, mutect2, varscan2
- FMO1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100707997; called by muse, mutect2, varscan2
- FOXJ2 | c.1163A>T p.Q388L | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); catalogued as rs1565630465, COSV50817472; called by muse, mutect2, varscan2
- FOXK1 | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196051; called by muse, mutect2
- FRG1 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV57005407, COSV99904141; called by muse, mutect2, varscan2
- FSIP2 | c.17020T>G p.Y5674D | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100556890; called by muse, mutect2, varscan2
- FSIP2 | c.20666C>A p.S6889Y | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100556891; called by muse, mutect2, varscan2
- G6PC2 | c.15C>A p.H5Q | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as COSV99960970; called by muse, mutect2, varscan2
- G6PC3 | c.78G>T p.W26C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52243540; called by muse, mutect2, varscan2
- GABPB1 | c.611A>T p.K204M | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99590231; called by muse, mutect2, varscan2
- GABRR3 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as COSV101512367; called by muse, mutect2, varscan2
- GALNT10 | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 80/368 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99770093; called by muse, varscan2
- GAPVD1 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99783916; called by mutect2, varscan2
- GBP5 | c.626-2A>T p.X209_splice | Splice Site (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100600191, COSV58593866; called by mutect2, varscan2
- GBP6 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969726, COSV65012144; called by muse, mutect2, varscan2
- GBP7 | c.862A>C p.T288P | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99643593; called by muse, mutect2, varscan2
- GFRA1 | c.812C>A p.S271* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100816297; called by mutect2, varscan2
- GJA8 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53788621, COSV99569809; called by muse, mutect2, varscan2
- GNAQ | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99682178; called by muse, mutect2, varscan2
- GPR12 | c.789C>A p.C263* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV101197933; called by muse, mutect2, varscan2
- GPR156 | c.1787C>G p.P596R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100251784, COSV59939007; called by muse, mutect2, varscan2
- GPR55 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV101235935; called by muse, mutect2, varscan2
- GRIA1 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV99602852; called by muse, mutect2
- GRIK2 | c.2636C>A p.P879Q | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as COSV59759746; called by muse, mutect2, varscan2
- GRIN2B | c.2368G>T p.E790* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as rs759594946, COSV101663223; called by muse, mutect2, varscan2
- GRM1 | c.1134C>A p.C378* | Nonsense Mutation (SNP) | VAF 52/159 reads (33%) | catalogued as COSV99269634; called by muse, mutect2, varscan2
- GRM1 | c.1135C>G p.R379G | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51113674, COSV99269636; called by muse, mutect2, varscan2
- GRM7 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100739259; called by muse, mutect2, varscan2
- GRM8 | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100286762; called by muse, mutect2, varscan2
- GSDMC | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 61/539 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52693098, COSV52693954; called by muse, mutect2, varscan2
- GUCY1A2 | c.326T>A p.L109H | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99977498; called by muse, mutect2, varscan2
- HDGFL3 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100220972; called by muse, mutect2, varscan2
- HELLS | c.1931G>T p.R644M | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99492484; called by muse, mutect2, varscan2
- HMCN1 | c.3125G>C p.G1042A | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); catalogued as COSV54895190, COSV99637427; called by muse, mutect2, varscan2
- HOXA3 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as COSV100415756, COSV57827995, COSV57828442; called by muse, mutect2, varscan2
- HTR1B | c.1042C>G p.L348V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100885521; called by muse, mutect2, varscan2
- HTT | c.5111A>G p.Y1704C | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.302); catalogued as rs1433865496, COSV61863199; called by muse, mutect2, varscan2
- HYDIN | c.2352C>G p.I784M | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV99865949; called by muse, varscan2
- IARS2 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV100228695; called by muse, mutect2, varscan2
- IGHG2 | c.688C>A p.L230M | Missense Mutation (SNP) | VAF 70/524 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.303); catalogued as rs771278286; called by muse, varscan2
- IGHV3-72 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 87/455 reads (19%) | catalogued as COSV101455380; called by muse, mutect2, varscan2
- IGKV1-17 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 141/534 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1473601437; called by muse, mutect2, varscan2
- IGSF11 | c.319A>T p.I107F (on ENST00000393775 / NM_001015887.3; = p.I106F on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/537 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV100678041; called by muse, mutect2, varscan2
- IGSF21 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99246604; called by muse, mutect2, varscan2
- IL2RA | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99906984; called by muse, mutect2, varscan2
- IL2RB | c.1643C>A p.T548N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV99345187; called by muse, mutect2, varscan2
- IL2RB | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.311); catalogued as COSV99345191; called by muse, mutect2, varscan2
- ILDR2 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs760889412, COSV54831479; called by muse, mutect2, varscan2
- IMPDH1 | c.1019G>T p.R340L (on ENST00000470772 / NM_001142573.2; = p.R426L on NM_000883.4) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100118839; called by muse, mutect2, varscan2
- IMPG2 | c.648G>T p.L216F | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99516696; called by muse, mutect2, varscan2
- INPP4B | c.2361G>T p.K787N | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.681); catalogued as COSV99527292; called by muse, mutect2, varscan2
- INPPL1 | c.1811G>T p.W604L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996756; called by muse, mutect2, varscan2
- INSR | c.1632G>T p.E544D | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100253781, COSV100254048; called by muse, mutect2, varscan2
- INSRR | c.1661G>T p.R554L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.366); catalogued as COSV100947774, COSV100948229; called by muse, varscan2
- INTS10 | c.838A>T p.S280C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV101208757; called by muse, mutect2, varscan2
- IQUB | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 22/167 reads (13%) | catalogued as COSV100227427; called by muse, mutect2, varscan2
- IRF8 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as COSV51900137; called by muse, mutect2, varscan2
- IRGQ | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100338279; called by muse, mutect2, varscan2
- ISL1 | c.842C>A p.P281Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV100045766; called by muse, mutect2, varscan2
- ITGA2 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1028073086, COSV99671839; called by muse, mutect2, varscan2
- ITGAD | c.1669G>C p.G557R | Missense Mutation (SNP) | VAF 86/492 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772879786, COSV101210622; called by muse, mutect2, varscan2
- JCAD | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs778946679, COSV100948628; called by muse, mutect2, varscan2
- KCNAB2 | c.212A>T p.Q71L | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV99379678; called by muse, mutect2
- KCNH6 | c.1128G>T p.K376N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100121304; called by muse, mutect2, varscan2
- KCNJ12 | c.845del p.G282Afs*27 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as COSV100054133; called by mutect2, varscan2
- KIAA0895 | c.817C>A p.P273T (on ENST00000297063 / NM_001100425.2; = p.P222T on NM_015314.3) | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as COSV99767320; called by muse, mutect2, varscan2
- KIAA1549L | c.801T>A p.S267R (on ENST00000321505; = p.S564R on NM_012194.3) | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV99684713; called by muse, mutect2, varscan2
- KIAA2026 | c.5107A>T p.S1703C | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV101199246; called by muse, mutect2
- KIF18B | c.2198A>T p.K733M (on ENST00000593135 / NM_001265577.2; = p.K745M on NM_001264573.2) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV100192687; called by muse, mutect2, varscan2
- KIF21A | c.4787A>C p.H1596P (on ENST00000361418 / NM_001378440.1; = p.H1583P on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/760 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.18); catalogued as COSV100735765; called by muse, mutect2, varscan2
- KIF7 | c.2191G>A p.G731R | Missense Mutation (SNP) | VAF 78/770 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101068103; called by muse, varscan2
- KLHL28 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753342; called by muse, mutect2, varscan2
- KMO | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 154/543 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV100844733; called by muse, mutect2, varscan2
- KMT2B | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV52890413, COSV52892053; called by muse, mutect2
- KPRP | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1251068129, COSV100908838; called by muse, mutect2, varscan2
- KRTAP11-1 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100190874; called by muse, mutect2, varscan2
- KRTAP13-2 | c.162G>T p.R54S | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101299670, COSV101299681, COSV67762116; called by muse, mutect2, varscan2
- LACRT | c.252G>A p.L84= | Splice Region (SNP) | VAF 10/164 reads (6%) | catalogued as COSV99143932; called by muse, mutect2
- LAMA1 | c.2812G>T p.G938C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101057994; called by muse, mutect2
- LCE3D | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.072); catalogued as rs749727744, COSV100909887; called by muse, mutect2, varscan2
- LDAH | c.819G>T p.W273C | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99426027; called by muse, mutect2, varscan2
- LHX8 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99634588; called by mutect2, varscan2
- LILRB5 | c.126del p.K43Sfs*3 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as COSV100300577, COSV60261450; called by mutect2, varscan2
- LIMS2 | c.110A>T p.H37L (on ENST00000355119 / NM_001161403.3; = p.H61L on NM_017980.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99760815; called by mutect2, varscan2
- LIX1L | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100811080; called by muse, mutect2, varscan2
- LMO7 | c.4527G>T p.Q1509H (on ENST00000357063; = p.Q1190H on NM_005358.5) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV100413988, COSV58541968; called by muse, mutect2, varscan2
- LPA | c.3723C>A p.N1241K | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV100308306; called by muse, mutect2, varscan2
- LPAR3 | c.953G>C p.R318T | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV101004891; called by muse, mutect2, varscan2
- LPXN | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 78/345 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101223171; called by muse, mutect2, varscan2
- LRP1B | c.13227G>T p.E4409D | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV101262140, COSV67262890; called by muse, mutect2, varscan2
- LRP1B | c.4018C>A p.L1340M | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV67218133; called by muse, varscan2
- LRRC32 | c.1766G>T p.R589L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.274); catalogued as rs565593386, COSV99477408; called by muse, varscan2
- LRRC66 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 85/510 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV58633823, COSV58636144; called by muse, mutect2, varscan2
- LRRIQ1 | c.4914G>T p.Q1638H | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV67831561; called by muse, varscan2
- LTBP1 | c.675C>A p.D225E | Missense Mutation (SNP) | VAF 114/662 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100618063; called by muse, mutect2, varscan2
- LUZP2 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV100421710, COSV61219643; called by muse, mutect2, varscan2
- LY6H | c.250T>C p.F84L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV100713959, COSV61370443; called by muse, mutect2
- MAGI1 | c.4198G>T p.D1400Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs370430462; called by muse, mutect2, varscan2
- MAP4K4 | c.892G>C p.V298L | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as COSV100156132; called by muse, mutect2, varscan2
- MBL2 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906436; called by muse, mutect2, varscan2
- MCM8 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1356448202, COSV99177633; called by muse, mutect2, varscan2
- MDC1 | c.3074A>T p.K1025M | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.187); catalogued as COSV100903146; called by muse, mutect2, varscan2
- MED26 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs540302307, COSV99660247; called by muse, mutect2, varscan2
- MEGF10 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 94/488 reads (19%) | catalogued as COSV99175863; called by muse, mutect2, varscan2
- MEOX2 | c.548T>A p.V183D | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as COSV100012623; called by muse, mutect2, varscan2
- MMD2 | c.560T>A p.L187H (on ENST00000404774 / NM_001100600.2; = p.L163H on NM_198403.4) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101287203; called by muse, mutect2, varscan2
- MMRN1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.444); catalogued as rs1374890443, COSV99307922; called by muse, mutect2, varscan2
- MMRN1 | c.2003C>G p.P668R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV99307923; called by mutect2, varscan2
- MORC4 | c.206G>T p.R69M | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99717730; called by muse, varscan2
- MORC4 | c.205A>G p.R69G | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.81); catalogued as COSV99717732; called by muse, varscan2
- MOXD1 | c.877C>A p.L293I | Missense Mutation (SNP) | VAF 65/324 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100382037; called by muse, mutect2, varscan2
- MPDZ | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV100065229; called by muse, mutect2, varscan2
- MRC1 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100509749, COSV58890064; called by muse, mutect2, varscan2
- MRGPRD | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100483105; called by muse, mutect2, varscan2
- MTR | c.1425G>T p.K475N | Missense Mutation (SNP) | VAF 138/542 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855603; called by muse, mutect2, varscan2
- MTTP | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV55504335; called by muse, varscan2
- MUC16 | c.41769G>T p.E13923D | Missense Mutation (SNP) | VAF 154/634 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.953); catalogued as COSV66692902; called by muse, mutect2, varscan2
- MUC16 | c.5012C>A p.S1671Y | Missense Mutation (SNP) | VAF 99/479 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV101201640; called by muse, mutect2, varscan2
- MUC16 | c.1805A>T p.Q602L | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV101202117; called by muse, mutect2, varscan2
- MYCBP2 | c.9707G>T p.S3236I (on ENST00000357337; = p.S3274I on NM_015057.5) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100632371; called by muse, mutect2, varscan2
- MYCBPAP | c.2815C>A p.L939I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs749299098, COSV99277542; called by muse, mutect2, varscan2
- MYEF2 | c.1682C>G p.S561* | Nonsense Mutation (SNP) | VAF 15/128 reads (12%) | catalogued as COSV99982274; called by muse, mutect2, varscan2
- MYH3 | c.2378G>T p.C793F | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV99879067; called by muse, mutect2, varscan2
- MYH7 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 65/362 reads (18%) | catalogued as COSV100806826; called by muse, mutect2, varscan2
- MYLK | c.4695C>A p.Y1565* | Nonsense Mutation (SNP) | VAF 58/269 reads (22%) | catalogued as COSV100659795; called by muse, mutect2, varscan2
- MYLK2 | c.1224+2T>A p.X408_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV101044981; called by muse, mutect2, varscan2
- NCAN | c.3342G>T p.K1114N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV53055254, COSV99388576; called by muse, mutect2, varscan2
- NCAN | c.3343G>T p.D1115Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99388578; called by muse, mutect2, varscan2
- NCOR1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1214744460, COSV99250464, COSV99252677; called by muse, mutect2, varscan2
- NCSTN | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV99617051; called by muse, mutect2, varscan2
- NEK1 | c.1283G>T p.S428I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV101455919, COSV71456982; called by muse, mutect2, varscan2
- NFATC2 | c.1905+1G>T p.X635_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV101043774, COSV101044853; called by muse, mutect2, varscan2
- NIBAN3 | c.185G>T p.C62F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.471); catalogued as COSV99962830; called by muse, mutect2, varscan2
- NLRC5 | c.3076C>T p.Q1026* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as rs759791431, COSV52658373; called by muse, mutect2, varscan2
- NLRP11 | c.1749C>A p.Y583* | Nonsense Mutation (SNP) | VAF 61/310 reads (20%) | catalogued as COSV100789830; called by muse, mutect2, varscan2
- NLRP13 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs893731940, COSV100738638; called by muse, mutect2, varscan2
- NLRP13 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100738315; called by muse, mutect2
- NLRP5 | c.2933C>A p.P978H | Missense Mutation (SNP) | VAF 148/978 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101173963, COSV66765677; called by mutect2, varscan2
- NMNAT3 | c.370C>A p.P124T (on ENST00000296202 / NM_001320512.1; = p.P87T on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99952135; called by muse, mutect2, varscan2
- NPY5R | c.746T>A p.L249H | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as COSV100642979; called by muse, mutect2, varscan2
- NRXN1 | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV68002975; called by muse, mutect2, varscan2
- NRXN2 | c.3406G>C p.G1136R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99636329; called by muse, varscan2
- NSD3 | c.1771A>T p.T591S | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100389014; called by muse, mutect2, varscan2
- NSDHL | c.702G>T p.L234F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV100938701; called by muse, mutect2, varscan2
- NSDHL | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as COSV100938703; called by muse, mutect2, varscan2
- NTNG1 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV53969555, COSV99640074; called by muse, mutect2, varscan2
- NTNG2 | c.586A>T p.T196S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100647832; called by muse, varscan2
- NTRK3 | c.2120C>A p.T707K | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV62296617; called by muse, mutect2, varscan2
- NTRK3 | c.1012A>T p.N338Y | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100448348; called by muse, mutect2, varscan2
- NUDT7 | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV99216255; called by muse, mutect2, varscan2
- NUDT7 | c.405G>C p.Q135H | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV99216257; called by muse, mutect2, varscan2
- NUGGC | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100429900; called by muse, mutect2, varscan2
- NUP98 | c.3636G>T p.M1212I (on ENST00000359171 / NM_001365126.1; = p.M1195I on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100263686; called by muse, mutect2, varscan2
- OBI1 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as rs767115602, COSV56144943, COSV99932679; called by muse, mutect2, varscan2
- OLFM3 | c.238G>T p.D80Y (on ENST00000338858 / NM_001288821.1; = p.D60Y on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100130248; called by muse, mutect2, varscan2
- OLFM4 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs373925038, COSV54581281; called by muse, mutect2, varscan2
- OMD | c.1123C>G p.L375V | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV100979100; called by muse, mutect2, varscan2
- OR10A6 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100564378, COSV59166205; called by muse, mutect2, varscan2
- OR10A7 | c.869A>G p.Y290C | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100406644; called by muse, mutect2, varscan2
- OR10C1 | c.306G>T p.M102I (on ENST00000622521; = p.M100I on NM_013941.3) | Missense Mutation (SNP) | VAF 83/454 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV101010897; called by muse, mutect2, varscan2
- OR10J1 | c.393A>T p.R131S | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV101420068; called by muse, mutect2
- OR13C8 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 132/585 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV100623044, COSV99080309; called by muse, mutect2, varscan2
- OR13C9 | c.68T>A p.L23H | Missense Mutation (SNP) | VAF 112/446 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1447535469, COSV99403596; called by muse, mutect2, varscan2
- OR1L1 | c.113G>C p.C38S | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1182247314, COSV100542294; called by muse, mutect2, varscan2
- OR2L13 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 95/520 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63547965, COSV63552086, COSV63559650; called by muse, mutect2, varscan2
- OR2M4 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 181/527 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as COSV100141587, COSV60708076, COSV60708583; called by muse, mutect2, varscan2
- OR2M4 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 99/253 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs746091746, COSV100141589; called by muse, mutect2, varscan2
- OR2T6 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100861666, COSV63215679; called by muse, varscan2
- OR2T6 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100861669; called by muse, varscan2
- OR4A5 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs760137860, COSV100157359; called by muse, mutect2, varscan2
- OR4D5 | c.768C>A p.Y256* | Nonsense Mutation (SNP) | VAF 62/356 reads (17%) | catalogued as COSV100190238; called by muse, mutect2, varscan2
- OR4K13 | c.760T>A p.C254S | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV100237934; called by muse, mutect2, varscan2
- OR4L1 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as rs747772078, COSV100235951; called by muse, mutect2, varscan2
- OR4P4 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745688826, COSV100111896; called by muse, varscan2
- OR52W1 | c.935C>A p.T312N | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1369217932, COSV100258768; called by muse, mutect2, varscan2
- OR5AS1 | c.658T>G p.C220G | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.322); catalogued as COSV100546427; called by muse, varscan2
- OR6K2 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 79/564 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs778393764, COSV100656924, COSV62744127; called by muse, mutect2, varscan2
- OR7A10 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.018); catalogued as COSV99932539; called by muse, mutect2
- OR7D4 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 94/672 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100432707, COSV100432899; called by muse, mutect2, varscan2
- OR9A2 | c.833C>G p.T278S | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); catalogued as COSV100628304; called by muse, mutect2, varscan2
- ORC2 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99309706; called by mutect2, varscan2
- OSCP1 | c.282G>T p.Q94H (on ENST00000356637 / NM_001330493.1; = p.Q84H on NM_145047.5) | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV99347664; called by muse, varscan2
- OTOF | c.5480G>T p.R1827L (on ENST00000272371 / NM_194248.3; = p.R1060L on NM_004802.4) | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV99719299; called by muse, mutect2, varscan2
- OTOL1 | c.524C>G p.P175R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.108); catalogued as COSV100020324; called by muse, mutect2
- OTX2 | c.488C>T p.P163L (on ENST00000408990 / NM_172337.3; = p.P171L on NM_021728.4) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV100258121, COSV59766937; called by muse, mutect2, varscan2
- OVCH1 | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100549343; called by muse, mutect2, varscan2
- PACRGL | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 104/529 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.487); catalogued as COSV99764413; called by muse, mutect2, varscan2
- PADI2 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100971118; called by muse, mutect2, varscan2
- PAGE3 | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100892005, COSV100892026; called by muse, mutect2, varscan2
- PAPPA2 | c.2672G>T p.R891L | Missense Mutation (SNP) | VAF 158/497 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100867259, COSV62772532; called by muse, mutect2, varscan2
- PARN | c.1416G>C p.Q472H | Missense Mutation (SNP) | VAF 195/832 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs766730789, COSV100420743; called by muse, mutect2, varscan2
- PASD1 | c.1844G>T p.R615I | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100949719; called by muse, varscan2
- PAX4 | c.584C>G p.P195R | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490386; called by muse, mutect2, varscan2
- PCDH11X | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs777825266, COSV53476341, COSV53478524; called by muse, mutect2, varscan2
- PCDHA3 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 65/281 reads (23%) | catalogued as COSV100793820, COSV100793834; called by muse, mutect2, varscan2
- PCDHA5 | c.2332G>T p.G778C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as rs782278628, COSV100972620; called by muse, mutect2, varscan2
- PCDHA8 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100971115; called by muse, mutect2
- PCDHB12 | c.1798del p.A600Pfs*31 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as COSV53395557; called by mutect2, pindel, varscan2
- PCDHGA1 | c.1622C>A p.P541H | Missense Mutation (SNP) | VAF 94/479 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV100966163; called by muse, mutect2, varscan2
- PDE10A | c.659G>C p.W220S | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.333); catalogued as COSV100606092; called by muse, mutect2, varscan2
- PDGFRA | c.1448C>G p.T483S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV99957951; called by muse, mutect2, varscan2
- PDILT | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.28); catalogued as rs1200321723, COSV100199884; called by muse, mutect2, varscan2
- PDXDC1 | c.1187A>T p.Q396L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as rs532163268, COSV100363524; called by muse, mutect2, varscan2
- PELP1 | c.1450G>T p.G484W | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV99343512; called by muse, mutect2, varscan2
- PIGA | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV100363572; called by muse, mutect2, varscan2
- PIK3CG | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100783274, COSV63247881; called by muse, mutect2, varscan2
- PIKFYVE | c.1560G>T p.E520D | Missense Mutation (SNP) | VAF 93/328 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV100011619; called by muse, mutect2, varscan2
- PLEKHA5 | c.2779A>G p.I927V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV100164905; called by muse, mutect2, varscan2
- PLXNA2 | c.3068G>C p.S1023T | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.324); catalogued as COSV100886146; called by muse, mutect2, varscan2
- PLXNA4 | c.2834C>A p.S945Y | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100327877, COSV58113459; called by muse, mutect2, varscan2
- PNLIPRP3 | c.277A>T p.I93L | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100982658; called by muse, mutect2, varscan2
- PNN | c.1703A>C p.N568T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV99397452; called by muse, mutect2
- POLR1A | c.2375A>T p.Y792F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.176); catalogued as rs775617280, COSV99808609; called by muse, mutect2, varscan2
- POT1 | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV62928517; called by muse, mutect2, varscan2
- PPA2 | c.939G>T p.S313= (on ENST00000341695 / NM_176869.3; = p.S284= on NM_006903.4) | Splice Region (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100500851, COSV58996044; called by muse, mutect2, varscan2
- PPFIA2 | c.3352C>A p.Q1118K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV100335591; called by muse, mutect2, varscan2
- PPHLN1 | c.277G>C p.A93P | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV99872507; called by muse, varscan2
- PPP6R3 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99677800; called by muse, mutect2, varscan2
- PRDM2 | c.5110A>G p.K1704E | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as rs1199131703, COSV99342944; called by muse, mutect2
- PRICKLE1 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100566717; called by muse, mutect2, varscan2
- PRKCG | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV99669662; called by muse, mutect2, varscan2
- PROS1 | c.1660G>T p.V554F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV101260915; called by muse, mutect2, varscan2
- PRPF19 | c.1133A>T p.D378V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99920823; called by muse, mutect2, varscan2
- PRPF3 | c.2018C>A p.A673E | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100255183; called by muse, mutect2, varscan2
- PRR16 | c.391C>T p.P131S (on ENST00000407149 / NM_001300783.2; = p.P108S on NM_016644.2) | Missense Mutation (SNP) | VAF 29/347 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as COSV101088418, COSV65398398; called by muse, mutect2
- PRR30 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99574884; called by muse, mutect2
- PSMA8 | c.102G>T p.A34= | Splice Region (SNP) | VAF 21/100 reads (21%) | catalogued as COSV100379201, COSV57601028; called by muse, mutect2, varscan2
- PTPRD | c.4949G>T p.R1650L | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100647633; called by muse, mutect2, varscan2
- PTPRD | c.2344G>T p.E782* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100647636, COSV61925280; called by muse, mutect2, varscan2
- PTPRJ | c.1874-1G>T p.X625_splice | Splice Site (SNP) | VAF 27/224 reads (12%) | catalogued as COSV101395808; called by muse, mutect2, varscan2
- PTPRK | c.3001G>T p.D1001Y (on ENST00000368215 / NM_001291984.2; = p.D1002Y on NM_002844.4) | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100951720; called by muse, mutect2, varscan2
- PXDNL | c.3166G>T p.G1056C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100687032; called by mutect2, varscan2
- PXDNL | c.2615G>T p.G872V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100687033, COSV62487345; called by muse, mutect2
- PXK | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100244515; called by mutect2, varscan2
- RABL3 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99846683; called by muse, mutect2, varscan2
- RAG1 | c.3047G>T p.G1016V | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100201225; called by muse, mutect2, varscan2
- RALGDS | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100924573; called by mutect2, varscan2
- RANBP6 | c.2812G>T p.G938C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424492; called by muse, varscan2
- RBBP4 | c.1042A>T p.S348C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV100995809; called by muse, mutect2, varscan2
- RBM28 | c.290G>C p.C97S | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99775979; called by muse, mutect2, varscan2
- REG3G | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.178); catalogued as COSV55450372, COSV55452555; called by muse, mutect2, varscan2
- RELN | c.9311A>G p.H3104R | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.854); catalogued as COSV100635128; called by muse, mutect2, varscan2
- REXO4 | c.641A>T p.K214M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV100905784; called by muse, mutect2, varscan2
- RGS22 | c.3629A>T p.Y1210F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100693949; called by muse, mutect2, varscan2
- RGS6 | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 72/351 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100667210; called by muse, mutect2, varscan2
- RNF20 | c.2846G>T p.R949L | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101206591, COSV66661379; called by mutect2, varscan2
- ROBO2 | c.3391A>T p.T1131S | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as COSV100170562; called by muse, mutect2, varscan2
- RRS1 | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV99398263; called by mutect2, varscan2
- RUNX1T1 | c.892C>A p.Q298K (on ENST00000265814 / NM_001198628.1; = p.Q271K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as COSV56153323, COSV99755718; called by muse, mutect2, varscan2
- RYR1 | c.2054G>T p.W685L | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617282; called by muse, mutect2, varscan2
- RYR1 | c.3770C>A p.S1257Y | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV100617283; called by muse, mutect2, varscan2
- RYR2 | c.10246G>T p.E3416* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100773271; called by muse, mutect2, varscan2
- RYR2 | c.12400G>T p.G4134C | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63683791; called by muse, mutect2, varscan2
- SAMD7 | c.440C>A p.A147D | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.479); catalogued as COSV100157125; called by muse, mutect2, varscan2
- SCN5A | c.6027C>A p.D2009E (on ENST00000333535 / NM_198056.3; = p.D2008E on NM_000335.5) | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100351178; called by muse, mutect2, varscan2
- SECISBP2 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 49/341 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as COSV100368920; called by muse, varscan2
- SELP | c.2264C>A p.S755* | Nonsense Mutation (SNP) | VAF 106/316 reads (34%) | catalogued as COSV99741353; called by muse, mutect2, varscan2
- SEMA3A | c.1084C>G p.P362A | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV99548260; called by muse, mutect2, varscan2
- SEMA3D | c.1558A>G p.I520V | Missense Mutation (SNP) | VAF 102/474 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99407559; called by muse, mutect2, varscan2
- SEMA5A | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101228770; called by muse, mutect2, varscan2
- SERPINA9 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.052); catalogued as COSV100098953; called by muse, mutect2, varscan2
- SERPINB12 | c.1036C>G p.H346D | Missense Mutation (SNP) | VAF 96/381 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99501955; called by muse, mutect2, varscan2
- SI | c.2278G>T p.A760S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100017520; called by muse, mutect2, varscan2
- SIDT1 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 57/408 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99334933; called by muse, mutect2, varscan2
- SIGLEC12 | c.576G>T p.K192N (on ENST00000291707 / NM_053003.4; = p.K74N on NM_033329.2) | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV99389669; called by muse, mutect2, varscan2
- SLC12A5 | c.217G>T p.E73* (on ENST00000454036 / NM_001134771.2; = p.E50* on NM_020708.5) | Nonsense Mutation (SNP) | VAF 19/135 reads (14%) | catalogued as COSV54794133, COSV99717057; called by muse, mutect2, varscan2
- SLC14A2 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 105/590 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV54907449, COSV99676309; called by muse, mutect2, varscan2
- SLC18A3 | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV100341079, COSV60334292; called by muse, mutect2
- SLC1A5 | c.1390G>T p.D464Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101314840; called by muse, mutect2, varscan2
- SLC22A1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as rs1045389610, COSV100267105; called by muse, mutect2, varscan2
- SLC23A3 | c.1798G>C p.E600Q (on ENST00000409878 / NM_001144889.2; = p.E483Q on NM_144712.5) | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs753216257, COSV99841456; called by muse, mutect2, varscan2
- SLC43A3 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100725281; called by muse, mutect2, varscan2
- SLC4A3 | c.1955A>T p.Y652F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.084); catalogued as COSV99813380; called by muse, mutect2, varscan2
- SLC4A3 | c.2735A>C p.K912T | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56096508, COSV99813384; called by muse, mutect2, varscan2
- SLC5A12 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 26/166 reads (16%) | catalogued as COSV101237782; called by muse, varscan2
- SLC5A12 | c.798del p.C266* | Frame Shift Del (DEL) | VAF 66/360 reads (18%) | catalogued as COSV54825104; called by mutect2, pindel, varscan2
- SLC7A13 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs776603092, COSV99879308; called by muse, mutect2, varscan2
- SLC8A3 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776416; called by muse, mutect2, varscan2
- SLC8A3 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776418; called by muse, mutect2, varscan2
- SLCO1C1 | c.1768G>T p.G590C | Missense Mutation (SNP) | VAF 167/663 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779608364, COSV99860177; called by muse, mutect2, varscan2
- SLCO2A1 | c.1614G>T p.M538I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100189486; called by muse, mutect2, varscan2
- SLIT1 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.306); catalogued as COSV99822783; called by muse, mutect2, varscan2
- SLITRK1 | c.1035C>A p.C345* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV101000102; called by muse, mutect2, varscan2
- SLITRK3 | c.1808G>C p.R603P | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99579206, COSV99580353; called by muse, mutect2, varscan2
- SMO | c.1571C>A p.A524D | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV50824992, COSV99977205; called by muse, mutect2, varscan2
- SMPD3 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99546154; called by muse, mutect2, varscan2
- SMYD1 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101352546; called by muse, mutect2, varscan2
- SNX16 | c.907G>T p.V303F | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100629724; called by muse, mutect2, varscan2
- SNX29 | c.934G>T p.G312W | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.947); catalogued as COSV100030478, COSV60061855; called by muse, mutect2, varscan2
- SPHK1 | c.346C>A p.L116M (on ENST00000392496 / NM_001355139.2; = p.L130M on NM_021972.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100039624; called by muse, mutect2, varscan2
- SPINK6 | c.121A>T p.T41S | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100347222; called by muse, mutect2
- SPTB | c.1513A>G p.N505D | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV101072473; called by muse, mutect2, varscan2
- SRRM2 | c.7693G>T p.G2565C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); catalogued as COSV99241783; called by muse, mutect2, varscan2
- ST6GAL2 | c.1339A>T p.M447L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | PolyPhen benign (0.001); catalogued as COSV100699705; called by muse, mutect2
- ST8SIA5 | c.723C>A p.N241K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | PolyPhen probably damaging (1); catalogued as COSV100165050; called by muse, mutect2, varscan2
- STC2 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.919); catalogued as COSV99438798; called by muse, mutect2, varscan2
- STIL | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV54552708, COSV99681435; called by muse, mutect2, varscan2
- STPG2 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99762080; called by muse, mutect2, varscan2
- SULT1C4 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 121/562 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV99731905; called by muse, mutect2, varscan2
- TAS2R60 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100223693; called by muse, mutect2, varscan2
- TBC1D28 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV100561098; called by muse, mutect2
- TBC1D28 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV100561102; called by muse, mutect2
- TBK1 | c.1669A>T p.N557Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV100538477; called by muse, mutect2
- TBX19 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 64/383 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV100892433; called by muse, mutect2, varscan2
- TCAF1 | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584746; called by muse, mutect2, varscan2
- TCL1A | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV101268500; called by muse, mutect2, varscan2
- TEKT4 | c.1177C>A p.L393I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99726631; called by muse, mutect2
- TENM2 | c.2585G>T p.C862F (on ENST00000518659 / NM_001122679.2; = p.C630F on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101319494; called by muse, mutect2
- TF | c.1019C>G p.T340S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as COSV99396526; called by muse, mutect2, varscan2
- TFAP2C | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.239); catalogued as rs748899621, COSV99571858; called by mutect2, varscan2
- THSD7B | c.1358G>C p.R453T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99759346; called by mutect2, varscan2
- TKTL2 | c.1147C>A p.R383S | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99761410; called by muse, mutect2, varscan2
- TM6SF2 | c.895G>C p.A299P | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV52268344, COSV99364097; called by muse, mutect2, varscan2
- TMEM108 | c.805A>T p.T269S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV58873083; called by muse, mutect2, varscan2
- TMEM161B | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV99680890; called by muse, mutect2
- TMEM178A | c.893G>T p.*298Lext*43 | Nonstop Mutation (SNP) | VAF 46/282 reads (16%) | catalogued as COSV99932102; called by muse, varscan2
- TMEM200A | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99760254; called by muse, mutect2, varscan2
- TMPRSS11F | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 58/299 reads (19%) | catalogued as COSV100678878; called by muse, mutect2, varscan2
- TNR | c.3406C>A p.Q1136K | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.763); catalogued as COSV99692092; called by muse, mutect2, varscan2
- TNR | c.2292G>T p.L764F | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99692097; called by muse, mutect2, varscan2
- TOP2B | c.1850A>T p.D617V (on ENST00000264331 / NM_001330700.2; = p.D612V on NM_001068.3) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV99980477; called by muse, mutect2, varscan2
- TOX2 | c.995C>T p.P332L (on ENST00000358131 / NM_001098798.2; = p.P308L on NM_032883.3) | Missense Mutation (SNP) | VAF 86/469 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100364855; called by muse, mutect2, varscan2
- TOX2 | c.1346G>T p.C449F (on ENST00000358131 / NM_001098798.2; = p.C425F on NM_032883.3) | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100364405; called by muse, mutect2, varscan2
- TRA2A | c.158G>T p.R53I | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.396); catalogued as COSV99767925; called by muse, mutect2, varscan2
- TRERF1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs770725567, COSV100551923; called by mutect2, varscan2
- TRIM23 | c.1290G>T p.M430I | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.29); catalogued as COSV99140333; called by muse, mutect2
- TRIM27 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV101019515; called by muse, mutect2, varscan2
- TRIM37 | c.2387-2A>C p.X796_splice | Splice Site (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99233599; called by mutect2, varscan2
- TRPA1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085491; called by muse, mutect2, varscan2
- TRPA1 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV100085495; called by muse, mutect2, varscan2
- TRPV4 | c.2465G>T p.W822L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV99028263; called by muse, mutect2, varscan2
- TRPV5 | c.1870G>T p.G624W | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521155; called by muse, mutect2, varscan2
- TRUB2 | c.240G>T p.L80= | Splice Region (SNP) | VAF 17/129 reads (13%) | catalogued as COSV55958499; called by muse, mutect2, varscan2
- TSC2 | c.2802G>T p.R934S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99555646; called by muse, mutect2, varscan2
- TSPAN18 | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV100419013; called by muse, mutect2, varscan2
- TTN | c.26768A>G p.K8923R (on ENST00000591111; = p.K7996R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | PolyPhen probably damaging (0.994); catalogued as COSV100634616; called by muse, mutect2, varscan2
- TTN | c.7927G>T p.V2643F (on ENST00000591111; = p.V2597F on NM_003319.4) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | PolyPhen probably damaging (0.998); catalogued as rs886042338, COSV100589579; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTPA | c.699G>T p.L233F | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99478661; called by muse, mutect2, varscan2
- TUBB8 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100226224; called by muse, mutect2, varscan2
- TYRP1 | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV101141494; called by muse, mutect2, varscan2
- UGT2B11 | c.669G>T p.W223C | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV101485313; called by muse, mutect2, varscan2
- UNC13C | c.816C>A p.H272Q | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV99524073; called by muse, mutect2, varscan2
- UNC5A | c.1941C>G p.D647E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as COSV99459604; called by muse, mutect2, varscan2
- UROS | c.466A>T p.K156* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100909085; called by muse, mutect2, varscan2
- USP17L2 | c.867C>A p.N289K | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.055); catalogued as COSV100414802; called by muse, mutect2, varscan2
- USP29 | c.2024C>T p.T675I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV99518846; called by muse, mutect2, varscan2
- USP34 | c.2233A>T p.I745F | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV101277293; called by muse, mutect2, varscan2
- USP6 | c.2901G>T p.W967C | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.962); catalogued as COSV100005148; called by muse, mutect2, varscan2
- VCAN | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99427713; called by muse, mutect2, varscan2
- VPS11 | c.1133C>T p.T378I (on ENST00000620429; = p.T922I on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV99598256; called by muse, mutect2, varscan2
- VPS13B | c.5147C>T p.T1716I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs966152558, COSV100663956; called by muse, mutect2, varscan2
- VPS54 | c.1011G>T p.R337= | Splice Region (SNP) | VAF 10/45 reads (22%) | catalogued as rs375030990; called by muse, mutect2, varscan2
- VPS8 | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV99804385; called by muse, mutect2, varscan2
- VWA8 | c.2845G>T p.E949* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV99865453; called by muse, mutect2, varscan2
- WDR64 | c.2616A>T p.Q872H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as COSV100844132; called by muse, mutect2, varscan2
- WDR7 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99590677; called by muse, mutect2, varscan2
- WDR93 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756537285, COSV99175887; called by mutect2, varscan2
- WFIKKN2 | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100260166; called by muse, mutect2, varscan2
- WHAMM | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as COSV54496118; called by muse, mutect2
- WSCD2 | c.1330C>T p.H444Y | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs761322445, COSV54578364, COSV99775407; called by muse, mutect2
- WWC1 | c.2406G>C p.M802I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99516146; called by muse, mutect2, varscan2
- WWC2 | c.3309G>T p.Q1103H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV101331123; called by muse, mutect2, varscan2
- XIRP2 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV99748736; called by muse, mutect2, varscan2
- XIRP2 | c.9385C>A p.R3129S (on ENST00000628543; = p.R3304S on NM_152381.6) | Missense Mutation (SNP) | VAF 117/732 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99748747; called by muse, mutect2, varscan2
- YARS1 | c.942A>T p.E314D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.884); catalogued as COSV100993528; called by muse, mutect2, varscan2
- YIPF7 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100274413; called by muse, mutect2, varscan2
- ZBBX | c.1565C>A p.S522Y | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV56785804, COSV56796180; called by muse, mutect2, varscan2
- ZBTB40 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 22/223 reads (10%) | catalogued as COSV100989142; called by muse, mutect2
- ZFHX4 | c.4851C>A p.H1617Q | Missense Mutation (SNP) | VAF 64/459 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99268888; called by muse, mutect2, varscan2
- ZFHX4 | c.5711C>A p.A1904D | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99268894; called by muse, mutect2, varscan2
- ZFYVE1 | c.1518G>T p.G506= | Splice Region (SNP) | VAF 39/264 reads (15%) | catalogued as COSV100607203; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as COSV100048632; called by muse, varscan2
- ZMYM4 | c.1927G>T p.V643L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV100111269; called by muse, mutect2, varscan2
- ZNF160 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as COSV100762515; called by muse, mutect2, varscan2
- ZNF19 | c.151A>T p.T51S | Missense Mutation (SNP) | VAF 100/614 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV99867777; called by muse, varscan2
- ZNF235 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs756560416, COSV52158623, COSV99349796; called by muse, mutect2, varscan2
- ZNF25 | c.175A>T p.K59* | Nonsense Mutation (SNP) | VAF 23/144 reads (16%) | catalogued as COSV100224826; called by muse, mutect2, varscan2
- ZNF256 | c.66C>A p.Y22* | Nonsense Mutation (SNP) | VAF 46/309 reads (15%) | catalogued as COSV99991113; called by muse, mutect2, varscan2
- ZNF317 | c.1576G>C p.G526R | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99927404; called by muse, mutect2, varscan2
- ZNF329 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100798842; called by muse, mutect2, varscan2
- ZNF385A | c.422-2A>T p.X141_splice (on ENST00000338010 / NM_001130967.3; = p.X121_splice on NM_015481.3) | Splice Site (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100567032; called by muse, mutect2, varscan2
- ZNF385B | c.1424G>T p.R475L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375494558, COSV100416545; called by muse, mutect2
- ZNF385D | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.981); catalogued as COSV99875039; called by muse, mutect2, varscan2
- ZNF407 | c.5557A>T p.S1853C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV100227476; called by muse, mutect2
- ZNF423 | c.884C>A p.P295Q (on ENST00000563137 / NM_001379286.1; = p.P287Q on NM_015069.4) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.967); catalogued as COSV52184195, COSV52201454; called by mutect2, varscan2
- ZNF43 | c.1236G>C p.K412N | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs879124559, COSV100731995; called by muse, mutect2, varscan2
- ZNF479 | c.1061C>A p.A354D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100483165; called by mutect2, varscan2
- ZNF480 | c.438G>T p.R146S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); catalogued as COSV57995388; called by muse, mutect2, varscan2
- ZNF483 | c.2218T>A p.F740I | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as COSV100493161; called by muse, mutect2, varscan2
- ZNF486 | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100631572; called by muse, mutect2, varscan2
- ZNF555 | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100514800; called by muse, mutect2, varscan2
- ZNF566 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV101091653; called by muse, mutect2, varscan2
- ZNF616 | c.1757A>T p.Y586F | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100348512, COSV100348680; called by muse, mutect2, varscan2
- ZNF626 | c.146A>T p.K49M | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV99391883; called by muse, mutect2, varscan2
- ZNF711 | c.1574G>T p.R525I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99341730; called by muse, mutect2, varscan2
- ZNF8 | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV99544622; called by muse, mutect2, varscan2
- ZNF816 | c.1196G>T p.C399F | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99554744; called by muse, mutect2, varscan2
- ZNF830 | c.510A>T p.E170D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as rs1229632912, COSV100031091; called by muse, mutect2, varscan2
- ZNF85 | c.563G>C p.C188S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100060205; called by muse, mutect2, varscan2
- ZZEF1 | c.1762A>G p.M588V | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV67556245; called by muse, mutect2, varscan2
- C3 | c.786del p.K263Rfs*40 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- CACNA1F | c.1914C>A p.H638Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CCDC178 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- COL11A1 | c.1921_1922del p.P641Kfs*6 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- DDX4 | c.1437G>T p.M479I | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, varscan2
- DKK2 | c.560del p.S187* | Frame Shift Del (DEL) | VAF 48/227 reads (21%) | called by mutect2, pindel, varscan2
- FCGBP | c.5656G>T p.G1886W | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FGF4 | c.484del p.L162Ffs*20 | Frame Shift Del (DEL) | VAF 17/123 reads (14%) | called by mutect2, pindel, varscan2
- GAK | c.2498del p.G833Dfs*112 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, varscan2
- GPR37 | c.561del p.K188Nfs*58 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- GRIPAP1 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 113/381 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- HHIPL2 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IGHM | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- IGLON5 | c.412A>C p.I138L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- KCNB2 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 42/341 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MDH1 | c.515del p.G172Vfs*2 | Frame Shift Del (DEL) | VAF 15/105 reads (14%) | called by mutect2, pindel, varscan2
- MGA | c.7481_7482insA p.L2495Sfs*11 (on ENST00000219905 / NM_001164273.1; = p.L2286Sfs*11 on NM_001080541.2) | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- MGA | c.7483C>A p.L2495M (on ENST00000219905 / NM_001164273.1; = p.L2286M on NM_001080541.2) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MUC16 | c.43163G>T p.G14388V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NMRK2 | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); called by muse, mutect2
- OR51B5 | c.23dup p.H8Qfs*41 | Frame Shift Ins (INS) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- RBP3 | c.795C>A p.D265E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- SERPINA9 | c.882del p.W294* | Frame Shift Del (DEL) | VAF 68/311 reads (22%) | called by mutect2, varscan2
- TDRD6 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TEX35 | c.668dup p.P224Afs*8 | Frame Shift Ins (INS) | VAF 20/84 reads (24%) | called by pindel, varscan2
- TRBC2 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TRGV5 | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- UBASH3B | c.1815C>A p.I605= | Splice Region (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- ZFHX4 | c.1814del p.G605Efs*28 | Frame Shift Del (DEL) | VAF 46/160 reads (29%) | called by mutect2, pindel, varscan2
- ZNF98 | c.656A>T p.Y219F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA4 | c.1353C>A p.I451= | Silent (SNP) | VAF 87/559 reads (16%) | catalogued as COSV100933332; called by muse, mutect2, varscan2
- ABCA8 | c.3177A>T p.T1059= | Silent (SNP) | VAF 71/156 reads (46%) | catalogued as COSV99287164; called by muse, mutect2, varscan2
- ACTBL2 | c.897G>T p.V299= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as COSV101379439; called by muse, varscan2
- ADCY6 | c.1023G>T p.L341= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as COSV100327006, COSV57168103; called by muse, mutect2, varscan2
- ADCY9 | c.3369G>A p.A1123= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs778234726, COSV53571497; called by muse, mutect2, varscan2
- ADRA2B | c.1338C>A p.T446= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1198721475, COSV101337399; called by muse, mutect2
- AGT | c.63C>A p.I21= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV100794507; called by muse, mutect2, varscan2
- ANK2 | c.6735A>G p.E2245= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as COSV100004705; called by muse, mutect2
- AP5S1 | c.222G>T p.R74= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99853338; called by muse, mutect2, varscan2
- APOB | c.12669G>A p.E4223= | Silent (SNP) | VAF 24/182 reads (13%) | catalogued as COSV99268634; called by muse, mutect2, varscan2
- ARAP3 | c.111G>A p.R37= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99500423; called by muse, mutect2, varscan2
- ATF6 | c.762A>C p.P254= | Silent (SNP) | VAF 42/242 reads (17%) | catalogued as COSV100909561; called by muse, mutect2, varscan2
- ATP4A | c.570G>A p.Q190= | Silent (SNP) | VAF 41/279 reads (15%) | catalogued as COSV99383191; called by muse, mutect2, varscan2
- C4orf51 | c.348T>C p.F116= | Silent (SNP) | VAF 59/287 reads (21%) | catalogued as COSV101440047; called by muse, mutect2, varscan2
- CARMIL2 | c.1807C>A p.R603= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100576404; called by mutect2, varscan2
- CCDC186 | c.976C>A p.R326= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as COSV100991149; called by muse, mutect2, varscan2
- CD180 | c.39G>T p.L13= | Silent (SNP) | VAF 32/523 reads (6%) | catalogued as COSV99842456; called by muse, mutect2
- CDO1 | c.456G>T p.V152= | Silent (SNP) | VAF 27/236 reads (11%) | catalogued as COSV99164846; called by muse, mutect2, varscan2
- CELF1 | c.1125C>T p.P375= (on ENST00000358597 / NM_001376422.1; = p.P371= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as COSV100137285; called by muse, mutect2, varscan2
- CEP128 | c.660G>T p.V220= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV99383826; called by muse, mutect2, varscan2
- CHRM2 | c.405G>T p.R135= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV100280681; called by muse, mutect2, varscan2
- CORO2B | c.108C>A p.I36= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as COSV99963848; called by muse, mutect2, varscan2
- CPB1 | c.1248G>C p.L416= | Silent (SNP) | VAF 52/322 reads (16%) | catalogued as COSV99294596; called by muse, mutect2
- CSGALNACT1 | c.543G>T p.V181= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV100175791; called by muse, varscan2
- CTRC | c.15T>A p.T5= | Silent (SNP) | VAF 30/186 reads (16%) | catalogued as COSV101036488; called by muse, mutect2, varscan2
- DHX16 | c.589C>T p.L197= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV100906185; called by muse, mutect2, varscan2
- DNAH7 | c.2280A>G p.Q760= | Silent (SNP) | VAF 34/242 reads (14%) | catalogued as COSV100418120; called by muse, mutect2, varscan2
- DNAI4 | c.1521C>T p.H507= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV100925363; called by muse, mutect2
- DNAJB8 | c.321G>T p.L107= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100048535; called by muse, mutect2, varscan2
- FAM83B | c.2736T>C p.P912= | Silent (SNP) | VAF 38/198 reads (19%) | catalogued as COSV100175182; called by muse, mutect2, varscan2
- FER1L6 | c.1791C>A p.S597= | Silent (SNP) | VAF 189/1289 reads (15%) | catalogued as COSV101206240; called by muse, mutect2, varscan2
- FHOD3 | c.450G>C p.L150= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV57184297; called by muse, mutect2, varscan2
- FIGN | c.1533G>T p.A511= | Silent (SNP) | VAF 103/408 reads (25%) | catalogued as rs767299659, COSV100293067, COSV60772231; called by muse, mutect2, varscan2
- FNIP2 | c.1998C>T p.P666= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100033395; called by muse, mutect2, varscan2
- GAL3ST4 | c.1078C>A p.R360= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs570514466, COSV100385672, COSV57586143; called by muse, mutect2, varscan2
- GBP7 | c.861C>A p.V287= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV99643595; called by muse, mutect2, varscan2
- GPR61 | c.270C>T p.A90= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as rs772632780, COSV101344423; called by muse, mutect2, varscan2
- GRID1 | c.1797G>T p.P599= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV100027064; called by muse, mutect2, varscan2
- GRIN3A | c.1068G>T p.L356= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs1236064909, COSV100701930; called by muse, mutect2, varscan2
- GRM5 | c.1779C>A p.A593= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as COSV100554959; called by muse, mutect2, varscan2
- HELZ | c.3648C>T p.Y1216= | Silent (SNP) | VAF 105/301 reads (35%) | catalogued as rs1229103623, COSV100699120; called by muse, mutect2, varscan2
- HTN1 | c.121C>A p.R41= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as rs371461805, COSV55895274, COSV99887607; called by muse, mutect2, varscan2
- HTT | c.6285G>T p.P2095= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100751373; called by muse, mutect2, varscan2
- IFNL2 | c.414G>T p.R138= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100122140; called by muse, mutect2, varscan2
- IGDCC4 | c.2481C>T p.G827= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1368090341, COSV100732646; called by mutect2, varscan2
- IGHA2 | c.213C>A p.T71= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- IGHV3-13 | c.253C>A p.R85= | Silent (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- IMPDH1 | c.1020G>T p.R340= (on ENST00000470772 / NM_001142573.2; = p.R426= on NM_000883.4) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100118838; called by muse, mutect2, varscan2
- ITPR1 | c.1065G>T p.L355= (on ENST00000354582; = p.L340= on NM_002222.7) | Silent (SNP) | VAF 106/368 reads (29%) | catalogued as COSV100233630; called by muse, mutect2, varscan2
- KIDINS220 | c.3231G>C p.L1077= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV99876614; called by muse, mutect2, varscan2
- KLHL14 | c.1656C>A p.L552= | Silent (SNP) | VAF 46/214 reads (21%) | catalogued as COSV100839331; called by muse, mutect2, varscan2
- LPA | c.3297C>A p.T1099= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as rs770611055, COSV100308309; called by muse, mutect2, varscan2
- LRP1B | c.1830A>T p.G610= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as COSV101262145; called by muse, varscan2
- LRRC27 | c.594G>T p.P198= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs774713378, COSV100690006, COSV59812391; called by muse, mutect2, varscan2
- LRRC32 | c.1950C>T p.C650= | Silent (SNP) | VAF 70/322 reads (22%) | catalogued as rs755948676, COSV99477407; called by muse, varscan2
- MARCO | c.777G>T p.G259= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100503916; called by muse, varscan2
- MATN4 | c.510G>T p.A170= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1335076126, COSV100637192; called by mutect2, varscan2
- MFSD13A | c.1029G>T p.L343= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99488111; called by muse, mutect2, varscan2
- MGAM | c.789G>T p.V263= | Silent (SNP) | VAF 34/255 reads (13%) | catalogued as COSV101516577; called by muse, mutect2, varscan2
- MMP26 | c.174G>T p.L58= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV100332288; called by muse, mutect2, varscan2
- MRPS36 | c.195G>C p.L65= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV99841137; called by muse, mutect2, varscan2
- MUC16 | c.43164G>T p.G14388= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1298302051; called by muse, mutect2, varscan2
- MUC16 | c.36195C>A p.S12065= | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2
- MXRA5 | c.6489C>A p.T2163= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99479764; called by muse, mutect2
- MYO1H | c.2652G>T p.P884= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as COSV100184106; called by muse, mutect2, varscan2
- NCR3 | c.357A>C p.T119= | Silent (SNP) | VAF 53/298 reads (18%) | catalogued as COSV99279232; called by muse, varscan2
- NEUROG2 | c.390G>T p.A130= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs773597723, COSV100511974; called by muse, mutect2, varscan2
- NFATC2IP | c.633G>A p.T211= | Silent (SNP) | VAF 87/438 reads (20%) | catalogued as rs755353194, COSV57909679, COSV57910436; called by muse, mutect2, varscan2
- NKX2-2 | c.24G>C p.T8= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV101010642, COSV65819216, COSV65820047; called by mutect2, varscan2
- NLRP11 | c.1575G>C p.S525= | Silent (SNP) | VAF 126/704 reads (18%) | catalogued as COSV100789831; called by muse, mutect2, varscan2
- NRXN1 | c.399G>T p.V133= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV101277109; called by muse, mutect2, varscan2
- NWD1 | c.2439G>T p.L813= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100343920; called by muse, mutect2, varscan2
- OR10H2 | c.703C>A p.R235= | Silent (SNP) | VAF 117/514 reads (23%) | catalogued as COSV100008907; called by muse, mutect2, varscan2
- OR11H4 | c.204C>A p.P68= | Silent (SNP) | VAF 49/296 reads (17%) | catalogued as COSV100197649, COSV59560585; called by muse, mutect2, varscan2
- OR2T5 | c.177C>T p.L59= | Silent (SNP) | VAF 67/571 reads (12%) | catalogued as rs1240557470, COSV100822223; called by muse, mutect2, varscan2
- OR2W3 | c.756T>C p.Y252= | Silent (SNP) | VAF 161/467 reads (34%) | catalogued as rs1180053252, COSV100831885; called by muse, mutect2, varscan2
- OR4D1 | c.453G>T p.G151= | Silent (SNP) | VAF 48/219 reads (22%) | catalogued as COSV99274362; called by mutect2, varscan2
- OR51T1 | c.396G>T p.L132= | Silent (SNP) | VAF 33/765 reads (4%) | called by muse, mutect2
- OR52K1 | c.774C>A p.V258= | Silent (SNP) | VAF 109/694 reads (16%) | catalogued as COSV100297758; called by muse, mutect2, varscan2
- OR52R1 | c.471G>T p.L157= | Silent (SNP) | VAF 47/235 reads (20%) | catalogued as COSV100617815; called by muse, mutect2, varscan2
- PCDHA7 | c.1791T>A p.V597= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100971952; called by muse, mutect2, varscan2
- PCDHB13 | c.1479C>T p.P493= | Silent (SNP) | VAF 55/286 reads (19%) | catalogued as COSV99507989; called by muse, mutect2, varscan2
- PCDHB4 | c.1155A>T p.P385= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV52020763; called by muse, mutect2
- PCDHGA6 | c.1236G>T p.R412= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV54025241, COSV54051204; called by muse, mutect2, varscan2
- PCDHGB2 | c.1695C>A p.P565= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV99528381, COSV99549024; called by muse, mutect2, varscan2
- PGK2 | c.525C>A p.S175= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as COSV100505748; called by muse, mutect2, varscan2
- PIAS3 | c.1083G>A p.K361= | Silent (SNP) | VAF 54/376 reads (14%) | catalogued as COSV100566889; called by muse, mutect2, varscan2
- PLPP7 | c.315C>A p.S105= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100952610; called by muse, varscan2
- POC5 | c.1485T>C p.D495= (on ENST00000428202 / NM_001099271.2; = p.D470= on NM_152408.2) | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100994416; called by muse, mutect2, varscan2
- POFUT1 | c.663G>T p.T221= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV101003226; called by muse, mutect2, varscan2
- PPP3R2 | c.285G>T p.A95= | Silent (SNP) | VAF 61/301 reads (20%) | catalogued as COSV100701928, COSV62450522; called by muse, mutect2, varscan2
- PPP6R3 | c.2196A>T p.T732= (on ENST00000393800 / NM_001352375.2; = p.T652= on NM_018312.5) | Silent (SNP) | VAF 77/326 reads (24%) | catalogued as COSV55733075; called by muse, mutect2, varscan2
- PRAM1 | c.180G>T p.P60= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99725927; called by muse, varscan2
- PRAMEF7 | c.1236T>A p.P412= | Silent (SNP) | VAF 24/306 reads (8%) | catalogued as rs1175729668; called by muse, mutect2
- PRSS23 | c.111C>T p.L37= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV99722635; called by muse, mutect2, varscan2
- PSG7 | c.450C>A p.S150= | Silent (SNP) | VAF 82/496 reads (17%) | catalogued as rs758858714, COSV68446862; called by muse, mutect2, varscan2
- PTAFR | c.450C>A p.S150= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as COSV100544521; called by muse, mutect2, varscan2
- RBM11 | c.66G>A p.R22= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV101271255; called by muse, mutect2, varscan2
- RNF150 | c.591C>A p.T197= | Silent (SNP) | VAF 221/965 reads (23%) | catalogued as COSV100154349; called by muse, mutect2, varscan2
- RP1L1 | c.6984C>G p.A2328= | Silent (SNP) | VAF 151/718 reads (21%) | catalogued as rs1329449767, COSV101223781; called by muse, mutect2, varscan2
- RPH3A | c.672C>A p.P224= (on ENST00000389385 / NM_001143854.2; = p.P220= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/303 reads (24%) | catalogued as COSV101231920; called by muse, mutect2, varscan2
- RYR3 | c.12084A>G p.L4028= (on ENST00000389232; = p.L4029= on NM_001036.6) | Silent (SNP) | VAF 22/162 reads (14%) | catalogued as COSV101215108; called by muse, mutect2, varscan2
- SEL1L2 | c.9C>A p.P3= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV99445717; called by muse, mutect2, varscan2
- SIGLEC5 | c.636C>A p.T212= | Silent (SNP) | VAF 42/267 reads (16%) | catalogued as COSV55780585, COSV99707934; called by muse, mutect2, varscan2
- SLC49A4 | c.366G>C p.L122= | Silent (SNP) | VAF 37/196 reads (19%) | catalogued as rs770000276, COSV99658833; called by muse, mutect2, varscan2
- SLCO2B1 | c.1212C>A p.I404= | Silent (SNP) | VAF 28/173 reads (16%) | catalogued as COSV99215304; called by muse, mutect2, varscan2
- SORBS1 | c.2694G>T p.R898= (on ENST00000361941 / NM_001034954.2; = p.R548= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/284 reads (16%) | catalogued as rs1219652501, COSV99529116; called by muse, varscan2
- SORCS1 | c.3232C>A p.R1078= | Silent (SNP) | VAF 41/232 reads (18%) | catalogued as COSV53849388, COSV99551147; called by muse, mutect2, varscan2
- SPATA13 | c.723G>T p.R241= | Silent (SNP) | VAF 31/162 reads (19%) | catalogued as COSV100542568; called by muse, mutect2, varscan2
- SPATA31D1 | c.990A>T p.L330= | Silent (SNP) | VAF 108/504 reads (21%) | catalogued as COSV100783130; called by muse, mutect2, varscan2
- SPATA31E1 | c.3171G>T p.S1057= | Silent (SNP) | VAF 70/369 reads (19%) | called by muse, mutect2, varscan2
- SPATC1 | c.369G>T p.T123= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101085403; called by muse, mutect2, varscan2
- SPTBN1 | c.4674C>T p.L1558= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as rs766394375, COSV100443593; called by muse, mutect2
- SYNDIG1 | c.534G>T p.P178= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs536225349, COSV100965456, COSV65233168; called by muse, mutect2, varscan2
- TASOR2 | c.1530A>G p.Q510= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs1268434915, COSV100051222; called by muse, mutect2
- TBC1D8 | c.1171T>C p.L391= | Silent (SNP) | VAF 61/564 reads (11%) | catalogued as rs768825686, COSV100964674; called by muse, varscan2
- TCERG1L | c.1083G>C p.T361= | Silent (SNP) | VAF 32/223 reads (14%) | catalogued as COSV100894667, COSV64046774; called by muse, mutect2, varscan2
- TEKT4 | c.93C>A p.T31= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99726815; called by muse, mutect2, varscan2
- TEP1 | c.3516G>A p.Q1172= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV99403521; called by muse, mutect2, varscan2
- TGM6 | c.567C>T p.I189= | Silent (SNP) | VAF 45/203 reads (22%) | catalogued as COSV99172947; called by muse, mutect2, varscan2
- TLN2 | c.2958G>T p.L986= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV60891810; called by muse, mutect2, varscan2
- TRIM25 | c.606G>T p.L202= | Silent (SNP) | VAF 44/160 reads (28%) | catalogued as COSV100381242, COSV57546104; called by muse, mutect2, varscan2
- TRIM58 | c.648G>T p.R216= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100825363; called by muse, mutect2
- TRPM1 | c.1348C>A p.R450= | Silent (SNP) | VAF 49/320 reads (15%) | catalogued as rs371853965, COSV56630696, COSV99856888; called by muse, mutect2, varscan2
- TRPM5 | c.573G>T p.P191= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs750055651, COSV99330700; called by muse, mutect2, varscan2
- TRPM7 | c.5556C>G p.T1852= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100540460; called by muse, mutect2, varscan2
- TTN | c.34800C>A p.A11600= (on ENST00000591111; = p.A10673= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100634615; called by muse, mutect2, varscan2
- TTN | c.23040C>A p.I7680= (on ENST00000591111; = p.I6753= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/222 reads (32%) | catalogued as COSV100634617; called by muse, mutect2, varscan2
- USP6 | c.84T>A p.A28= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100005147; called by muse, varscan2
- VWCE | c.1935G>A p.V645= | Silent (SNP) | VAF 35/290 reads (12%) | catalogued as rs1434730651, COSV100076263; called by muse, mutect2, varscan2
- WDR37 | c.537C>T p.H179= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV99580307; called by muse, varscan2
- XIRP2 | c.1029C>T p.I343= (on ENST00000628543; = p.I518= on NM_152381.6) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99748740; called by muse, mutect2, varscan2
- XIRP2 | c.8934C>A p.P2978= (on ENST00000628543; = p.P3153= on NM_152381.6) | Silent (SNP) | VAF 47/221 reads (21%) | catalogued as COSV99748745; called by muse, mutect2, varscan2
- XPNPEP2 | c.1818G>C p.L606= | Silent (SNP) | VAF 92/377 reads (24%) | catalogued as COSV100941571; called by muse, mutect2, varscan2
- ZBTB32 | c.123C>A p.P41= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99386314; called by muse, mutect2, varscan2
- ZFAND3 | c.252G>T p.P84= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs748675513, COSV54730379, COSV99765983; called by muse, mutect2, varscan2
- ZNF263 | c.1272A>G p.L424= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV99527207; called by muse, mutect2, varscan2
- ZNF275 | c.213G>A p.R71= | Silent (SNP) | VAF 57/256 reads (22%) | catalogued as rs370098208, COSV100936486; called by muse, mutect2, varscan2
- ZSCAN1 | c.390G>T p.S130= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99992196; called by muse, varscan2
- ABHD5 | c.*21G>T | 3'UTR (SNP) | VAF 19/98 reads (19%) | catalogued as COSV101369696; called by muse, mutect2, varscan2
- AL136982.4 | n.678T>C | RNA (SNP) | VAF 52/283 reads (18%) | called by muse, varscan2
- ANKRD33 | c.-194G>T | 5'UTR (SNP) | VAF 33/105 reads (31%) | catalogued as rs755881373, COSV56607380; called by muse, varscan2
- ANKRD33 | c.-95T>G | 5'UTR (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100001586; called by muse, varscan2
- ATP13A3 | c.*2A>C | 3'UTR (SNP) | VAF 21/141 reads (15%) | catalogued as COSV99757767; called by muse, mutect2, varscan2
- BTN2A3P | n.210C>T | RNA (SNP) | VAF 26/171 reads (15%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445671 A>T | 3'Flank (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1729-59G>T | Intron (SNP) | VAF 46/180 reads (26%) | catalogued as COSV100026259; called by muse, mutect2, varscan2
- MIR133B | n.35C>T | RNA (SNP) | VAF 44/249 reads (18%) | called by muse, mutect2, varscan2
- MIR518D | n.57G>A | RNA (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2143T>A | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99485717; called by muse, varscan2
- PRR12 | c.51+580G>A | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101330839, COSV69816564; called by mutect2, varscan2
- RBM44 | c.-41G>A | 5'UTR (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100390248; called by muse, mutect2
- SLC26A7 | c.1935+212C>A | Intron (SNP) | VAF 19/168 reads (11%) | catalogued as rs1425720200, COSV52586373; called by muse, mutect2, varscan2
- SLIT2 | c.1463-590C>A | Intron (SNP) | VAF 23/117 reads (20%) | catalogued as COSV99887950, COSV99888058; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1908G>T | Intron (SNP) | VAF 64/254 reads (25%) | catalogued as COSV100678881; called by muse, mutect2, varscan2
- TTN | c.10360+1462T>G | Intron (SNP) | VAF 30/166 reads (18%) | catalogued as COSV100634618; called by muse, mutect2, varscan2
- WNK1 | c.2140-3149A>T | Intron (SNP) | VAF 37/209 reads (18%) | catalogued as COSV100268892; called by muse, mutect2, varscan2
- XIST | n.11277G>T | RNA (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ZAN | c.7787+17C>A | Intron (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100770548; called by muse, mutect2, varscan2
